Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A20F, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A20F-06A (Metastatic).

DOB/Age/Sex: years Male
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

(1). (R) pelvic nodes. Our Bank. Histopathology.

1 CB-0-3

Melanoma, NOS 8720/3

MACROSCOPIC DESCRIPTION

(Dr

Site: lymph node, iliac + obturator
c77.5 c77.5

Two specimens were received.

hw 3/30/11

1. "RIGHT COMMON EXTERNAL ILIAC AND OBTURATOR NODES". A large nodule 40 x 40 x 50mm covered by a thin membranous-like tissue with attached fatty tissue up to 50mm. The cut surface shows white tan appearance with a central area of necrosis. In addition, there are two large fragments of tissue with similar appearance to the large nodule. In addition, there are multiple lymph nodes present within the attached fatty tissue. The largest node measures 25mm across. Sampled fresh state from the large nodule (

A-B. From the large nodule.

C-D. Sections from the separate fragmented tumour tissue.

E. One node bisected (the largest node).

F. Two nodes.

G. One node.

H. Four nodes.

2. "RIGHT INTERNAL ILIAC NODE". A probable lymph node 10mm in maximum extent, with surrounding fatty tissue up to 20mm. All embedded.

MICROSCOPIC REPORT

1. "RIGHT COMMON EXTERNAL ILIAC AND OBTURATOR NODES". The large nodule is a nodal deposit of metastatic melanoma (S100 positive on immunostaining). Eight additional lymph nodes were found which show no evidence of malignancy.

2. "RIGHT INTERNAL ILIAC NODE". One lymph node shows no evidence of malignancy.

SUMMARY

1. "RIGHT COMMON EXTERNAL ILIAC AND OBTURATOR NODES" - One of nine nodes shows metastatic malignant melanoma.

2. "RIGHT INTERNAL ILIAC NODE" - No evidence of malignancy

REPORTED BY: Dr.

IIIPA Discrepancy		

hw 3/30/11

Printe

Source: NCI Genomic Data Commons file 938319ff-b0cc-4b0d-83d3-366967882bb7 (TCGA-EE-A20F.9B0E65BC-811F-461B-9A15-21F8BEC96667.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).